Somatic mutation profile of tumor specimen TCGA-AA-3688-01A (aliquot TCGA-AA-3688-01A-01W-0900-09) from TCGA case TCGA-AA-3688, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 80.0 years (29,220 days).
Specimen TCGA-AA-3688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cbab987-3749-46c5-8f15-2719cbe1d058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3688-10A (Blood Derived Normal), aliquot TCGA-AA-3688-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8caf2a97-cbbd-492c-a225-c5a018b321ed

The open-access MAF lists 77 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Nonsense Mutation 7, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 26/36 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs864622237, CM137618, COSV52694920, COSV52730114, COSV52730255; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV51623410; called by muse, mutect2, varscan2
- ABCA13 | c.11815T>C p.F3939L | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71295950; called by muse, mutect2, varscan2
- ADCY8 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.013); catalogued as rs147278965, COSV53934527; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 105/140 reads (75%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- ARMC4 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 14/236 reads (6%) | catalogued as COSV99519164; called by muse, mutect2
- BCL11A | c.2081C>T p.P694L (on ENST00000335712 / NM_001365609.1; = p.P728L on NM_018014.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs866545562, COSV59638808; called by muse, mutect2
- BICC1 | c.2726A>C p.D909A | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100875015; called by muse, mutect2
- CACNA1I | c.4648C>T p.R1550* | Nonsense Mutation (SNP) | VAF 59/67 reads (88%) | catalogued as rs747185563, COSV60801133; called by muse, mutect2, varscan2
- CCDC160 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 62/73 reads (85%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV66251606, COSV66252048; called by muse, mutect2, varscan2
- CEBPZ | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV50019229; called by muse, mutect2, varscan2
- CHRM2 | c.1316G>A p.C439Y | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57786493; called by muse, varscan2
- CHSY1 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV54256600; called by muse, mutect2, varscan2
- CNTNAP2 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs369724886, COSV62260830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs371401173, COSV50569005; called by muse, mutect2, varscan2
- CR1 | c.5492G>A p.G1831E | Missense Mutation (SNP) | VAF 73/439 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65464633; called by muse, mutect2, varscan2
- CRISP1 | c.67-1G>A p.X23_splice | Splice Site (SNP) | VAF 143/372 reads (38%) | catalogued as rs1163196662, COSV59993424; called by muse, mutect2, varscan2
- CSMD2 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs777881521, COSV53891400; called by muse, mutect2, varscan2
- CTNND2 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 31/534 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs772092439, COSV58896689; called by muse, mutect2
- DIRAS2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs779203948, COSV65370071; called by muse, mutect2, varscan2
- DNHD1 | c.13772G>A p.R4591H | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs200510327, COSV54433847, COSV54437579; called by muse, mutect2, varscan2
- EPHA3 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 325/402 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60731233; called by muse, mutect2, varscan2
- EPX | c.1937A>T p.D646V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV56599790; called by muse, mutect2, varscan2
- GRIK3 | c.1546G>T p.V516L | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV66148206; called by muse, mutect2, varscan2
- GRIN2A | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV58020005, COSV58059516; called by muse, mutect2, varscan2
- GUCY1B1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs763812533, COSV100026017; called by muse, mutect2, varscan2
- ITGA2 | c.718T>A p.S240T | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV56867683; called by muse, mutect2, varscan2
- JAKMIP2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV99509482; called by muse, mutect2, varscan2
- KIF13A | c.3220C>T p.Q1074* | Nonsense Mutation (SNP) | VAF 10/117 reads (9%) | catalogued as COSV52468400; called by muse, mutect2
- MAP3K21 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 101/166 reads (61%) | catalogued as COSV64041616; called by muse, mutect2, varscan2
- MEIS1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55493430; called by muse, mutect2, varscan2
- MIGA1 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66225234; called by muse, mutect2, varscan2
- MMS19 | c.1988C>T p.T663I | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); catalogued as rs1262630655, COSV59137805; called by muse, mutect2, varscan2
- MYBPH | c.665T>G p.M222R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55144495; called by muse, mutect2
- NBEA | c.2929A>C p.K977Q | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.831); catalogued as COSV59786451, COSV59829993; called by muse, mutect2, varscan2
- NLRP6 | c.1068G>C p.K356N | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56462489; called by mutect2, varscan2
- NOL4 | c.1283C>A p.P428Q | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52358298; called by muse, mutect2, varscan2
- NR2C2 | c.518G>A p.R173Q (on ENST00000393102; = p.R192Q on NM_003298.5) | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60147881; called by muse, mutect2, varscan2
- NUP93 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV57429484; called by muse, mutect2, varscan2
- OR13F1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs201311592, COSV58252861; called by muse, mutect2, varscan2
- OR2L13 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 43/684 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV63556374; called by muse, mutect2
- PAM | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57221142; called by muse, mutect2, varscan2
- PCNA | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV52533570; called by muse, mutect2, varscan2
- PHTF1 | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1344660861, COSV63369156; called by muse, mutect2
- PKDREJ | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.028); catalogued as rs1028087642, COSV53548907, COSV53552298; called by muse, mutect2, varscan2
- PLXNC1 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs751117319, COSV51568591; called by muse, mutect2, varscan2
- PRKCE | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs752964225, COSV60321755; called by muse, mutect2, varscan2
- RGS6 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59567017; called by muse, mutect2, varscan2
- SBNO1 | c.2938C>T p.R980C (on ENST00000420886; = p.R979C on NM_018183.5) | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242567801, COSV57346769; called by muse, mutect2, varscan2
- SDK1 | c.3610G>A p.G1204R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1254436709, COSV67369533, COSV67384216; called by muse, mutect2, varscan2
- SEC16B | c.1450T>A p.W484R | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV57630815; called by muse, mutect2, varscan2
- SERAC1 | c.1358A>G p.Y453C | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65598257; called by muse, mutect2, varscan2
- SLA | c.227G>T p.C76F (on ENST00000338087 / NM_001045556.3; = p.C116F on NM_006748.4) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV55097354; called by muse, mutect2, varscan2
- SPAG17 | c.5093C>A p.A1698E | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV60470235; called by muse, mutect2, varscan2
- THBS2 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100828150; called by muse, mutect2
- TRIM48 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101338379; called by muse, mutect2
- ZNF208 | c.2807A>C p.K936T | Missense Mutation (SNP) | VAF 169/393 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101237161, COSV68101234, COSV68109514; called by muse, mutect2, varscan2
- ZNF300 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 149/202 reads (74%) | catalogued as COSV51054377; called by muse, mutect2, varscan2
- EPHA5 | c.1448dup p.N483Kfs*21 | Frame Shift Ins (INS) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- P3H4 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- SCN1A | c.196_203del p.G66Sfs*19 | Frame Shift Del (DEL) | VAF 69/188 reads (37%) | called by mutect2, pindel, varscan2
- ZSCAN2 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL9L | c.1680C>T p.P560= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV52690014; called by muse, mutect2, varscan2
- BICRA | c.33C>T p.D11= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs1201905676, COSV67604261; called by muse, mutect2, varscan2
- BOD1L1 | c.8949G>A p.E2983= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as COSV50089626; called by muse, mutect2
- CERK | c.174C>T p.I58= | Silent (SNP) | VAF 161/218 reads (74%) | catalogued as rs763776348, COSV53453632; called by muse, mutect2, varscan2
- CMKLR1 | c.711A>C p.T237= (on ENST00000312143 / NM_001142344.2; = p.T235= on NM_004072.3) | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV56442536; called by muse, mutect2, varscan2
- GRM7 | c.1078A>C p.R360= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV63167876; called by muse, mutect2
- IL12B | c.960C>T p.S320= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as rs752964137, COSV51456277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGI2 | c.1599A>G p.P533= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV100836962; called by muse, mutect2
- MAP1A | c.5130C>T p.H1710= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs766162870, COSV55813838; called by muse, mutect2, varscan2
- MYH6 | c.1968T>C p.N656= | Silent (SNP) | VAF 30/45 reads (67%) | catalogued as COSV62455333; called by muse, mutect2, varscan2
- PCDHGA1 | c.2139G>A p.A713= | Silent (SNP) | VAF 38/52 reads (73%) | catalogued as COSV65297396; called by muse, mutect2, varscan2
- PLEKHA4 | c.471C>T p.D157= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV54363948; called by muse, mutect2, varscan2
- SP140 | c.1593C>A p.V531= | Silent (SNP) | VAF 107/258 reads (41%) | catalogued as COSV59455984; called by muse, mutect2, varscan2
- STAT1 | c.1504C>T p.L502= | Silent (SNP) | VAF 91/239 reads (38%) | catalogued as rs777616424, COSV63117696; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827237 C>T | 3'Flank (SNP) | VAF 191/211 reads (91%) | catalogued as rs781177871; called by muse, mutect2, varscan2
